Surgical pathology report (de-identified scan), TCGA case TCGA-BA-4074, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-4074-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY

Diagnosis:

A: Vallecular lesion, biopsy.

- Fragment of lymphoid tissue and squamous epithelium forming squamous crypts, no tumor seen.

B: Posterior lateral tongue mucosa, removal.

- No tumor seen.

C: Right surface mucosa, margin, biopsy.

- No tumor seen.

D: Left surface mucosa, margin, biopsy.

- No tumor seen.

E: Posterior muscle margin, biopsy.

- No tumor seen.

F: Right muscle margin, biopsy.

- No tumor seen.

G: Floor of mouth mucosa margin, biopsy.

- No tumor seen.

H: Floor of mouth muscle margin, biopsy.

- No tumor seen.

I: Left tongue, hemiglossectomy.

- Squamous cell carcinoma, poorly differentiated, tumor extensively involves specimen with tumor size approximately 4.0 cm in greatest dimension, and diffusely involves deep margin of resection (black ink).

- Medial and lateral margins free of tumor.

J: Right neck lymph nodes and neck contents, regional node dissection.

- Metastatic squamous cell carcinoma involving 2 of 22

[page 2 of 7]
lymph nodes (lymph node count by level: Level I - 1 of 2, Level II - 1 of 4, Level III - 0 of 5, Level IV - 0 of 8, Level V - 0 of 3), size of largest metastasis 2.0 cm in greatest dimension, with extracapsular extension of tumor identified. Submandibular gland with no tumor seen.

K: Left neck lymph nodes and cervical contents, regional node dissection.

- Metastatic squamous cell in 3 of 25 lymph nodes (lymph node count by level: Level I - 2 of 4, Level II - 1 of 9, Level III - 0 of 8, Level IV - 0 of 4), size of largest metastasis 1.8 cm, with extracapsular extension of tumor identified.

- Tumor abuts the connective tissue around the submandibular gland, but no definite intrasubmandibular extension of tumor identified.

L: Left Level I fibrofatty tissue, removal.

- Fibrosis and acute and chronic inflammation, no tumor seen.

M: Floor of mouth, partial removal.

- Fragment of squamous mucosa and submucosa with minor salivary glands present, no tumor seen.

Comment:

Intraoperative Consultation:

A frozen section consultation was requested by [REDACTED].

FSA1: Vallecular lesion, biopsy

- No tumor seen, lymphoid tissue and squamous crypt present

FSB1: Posterior lateral tongue mucosa, removal

- No tumor identified

FSC1: Right surface mucosa, margin, biopsy

- No tumor identified

FSD1: Left surface mucosa, margin, biopsy

- No tumor identified

FSE1: Posterior muscle margin, biopsy

- No tumor identified

[page 3 of 7]
FSF1: Right muscle margin, biopsy
- No tumor identified

FSG1: Floor of mouth mucosa margin, biopsy
- No tumor identified

FSH1: Floor of mouth muscle margin, biopsy
- No tumor identified

Clinical History:

The patient is with T2N2M0 squamous cell carcinoma of the tongue and separate lesion on the right vallecula who undergoes bilateral radical neck dissection and hemiglossectomy.

Gross Description:

Container A holds two fragments of pink soft tissue measuring 0.8 x 0.8 x 0.4 cm in aggregate. (Block FSA1, NTR)

Container B holds a 0.8 x 0.3 x 0.3 cm red soft tissue fragment; block FSB1, NTR.

Container C holds a 1.1 x 0.4 x 0.3 cm red/tan soft tissue fragment; block FSC1,

Container D holds a 0.5 x 0.3 x 0.2 cm red/tan soft tissue fragment; block FSD1,

Container E holds a 0.4 x 0.2 x 0.2 cm red/tan soft tissue fragment; block FSE1,

Container F holds a 0.4 x 0.3 x 0.2 cm red/tan soft tissue fragment; block FSF1,

Container G holds a 0.5 x 0.2 x 0.2 cm soft tissue fragment; block FSG1,

Container H holds a 0.5 x 0.2 x 0.2 cm soft tissue fragment; block FSH1,

Container I:

[page 4 of 7]
Specimen fixation: received fresh and fixed in formalin

Type of specimen: left hemiglossectomy

Size of specimen: 4.4 cm anterior to posterior, 3.4 cm medial to lateral, and 2 cm superficial to deep

Orientation of specimen: A short stitch marks lateral, a long stitch marks anterior; the medial margin is inked green, the deep margin is inked black.

Tumor description: white, solid mass with an infiltrative border; no necrosis or hemorrhage is identified

Location of tumor: tumor is located on the deep aspect and runs almost the entire length anterior to posterior and is located more medially

Tumor size: 4 cm anterior to posterior, 2.5 cm medial to lateral, 1.2 cm superficial to deep

Extent of tumor: not applicable

Presence/absence of bone involvement: not applicable

Distance of tumor from surgical margins: 1.8 cm from the anterior surface, 0.7 cm from the posterior surface, 0.6 cm from the lateral surface, abuts medial margin, superseded by frozen; abuts deep margin, superseded by frozen; abuts superficial surface

Description of remainder of tissue: The surface of the tongue is pink/tan with a 1 x 0.2 cm disruption on the lateral/posterior aspect.

Tissue submitted for special investigation: none

Lymph nodes: submitted separately as neck dissection

Block Summary:

Sections submitted from anterior to posterior.

I1-I4 - representative sections of tumor abutting deep margin

I5 - representative section of lateral superficial

[page 5 of 7]
disruption .

I6 - representative section of tumor abutting medial margin

Container J is additionally labeled "right neck contents."
It contains a 14 x 8 x 2 cm segment of soft tissue including Levels I-V. Level I contains a 4 x 2 x 0.7 cm gland with a tan lobulated cut surface which does not appear involved by tumor. Three lymph node candidates are identified ranging in size from 0.5 to 1.4 cm. The largest is bisected.

J1 - one lymph node candidate, bisected; two additional candidates

J2 - additional fatty tissue

J3 - representative section of gland

Level II contains a 2 x 1.8 x 1.2 cm lymph node candidate identified which is grossly positive for tumor with a tan cut surface exhibiting areas of hemorrhage and necrosis. A 1 cm portion of vessel with a diameter of 0.7 cm is identified and opened to reveal a smooth surface uninvolved by tumor.

J4, J5 - large lymph node candidate, quadrisected

J6, J7 - additional representative tissue

In Level III, two lymph node candidates are identified ranging in size from 0.4 to 0.9 cm as well as additional adipose tissue and skeletal muscle.

J8 - lymph node candidate, submitted whole

J9, J10 - additional tissue with possible lymph node candidate

Level IV: Four lymph node candidates are identified ranging in size from 0.3 to 0.5 cm.

J11 - four lymph node candidates

J12, J13 - additional fatty tissue with possible lymph node candidates

Level V: No large nodes are identified.

J14, J15 - soft tissue with possible lymph node candidate

Container K is additionally labeled "left neck." It contains a 16 x 7.2 x 3.2 cm segment of tissue with Levels

[page 6 of 7]
I-IV.

Level I contains a 5 x 2 x 1 cm gland with tan lobulated cut surface on one end and a white/tan grossly positive cut surface of the other end. One lymph node candidate is identified measuring 2 cm in greatest diameter and is grossly positive on cut surface.

K1-K2 - representative sections of grossly involved gland
K3 - representative section of uninvolved portion of gland with one lymph node candidate
K4 - one lymph node candidate, bisected

Level II contains seven lymph node candidates ranging in size from 0.6 to 1.7 cm. The largest is bisected to reveal a white cut surface.

K5 - largest node, bisected and two additional small nodes
K6 - four lymph node candidates
K7-K8 - additional tissue with possible lymph node candidate

Level III contains five lymph node candidates ranging in size from 0.6 to 0.9 cm.

K9 - five lymph node candidates
K10 - additional representative tissue with possible lymph node candidate

K11, K12 - additional representative tissue with possible lymph node candidate

Level IV contains no large lymph node candidates. The soft tissue is submitted in blocks K13-K15.

Container L is additionally labeled "left Level I fibrofatty tissue." It contains a 1.5 x 1.0 x 0.5 cm segment of pink/tan soft tissue; block L1, NTR.

Container M is additionally labeled "floor of mouth." It contains a 1.6 x 1.0 x 0.4 cm segment of brown soft tissue;

[page 7 of 7]
block M1, [REDACTED]

Light Microscopy:

Light microscopic examination is performed by [REDACTED]

(Specimen I)

Histologic tumor type: squamous cell carcinoma

Histologic grade: poorly differentiated

Tumor extent: Tumor extensively involves the glossectomy specimen and measures approximately 4.0 cm in greatest dimension.

Presence/absence of angiolymphatic space invasion: not definitively identified

Histologic assessment of surgical margins: deep margin extensively involved with tumor

Lymph nodes: Metastatic squamous cell carcinoma in 2 of 22 right neck nodes, metastatic squamous cell carcinoma in 3 of 25 left neck nodes.

Size of largest nodal metastasis (greatest dimension): 2.0 cm on right, 1.8 cm on left

Presence/absence of extranodal extension: present, bilaterally

Other significant findings: not applicable

Source: NCI Genomic Data Commons file 5ab0ef86-3653-4955-b9f9-2946b2089e72 (TCGA-BA-4074.21249FF8-A752-46E6-82D9-ECAF7F025AFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).